Surgical pathology report (de-identified scan), TCGA case TCGA-A5-A0GP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cedars Sinai, specimen TCGA-A5-A0GP-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3

11/23/10

Site: Endometrium c54.1

Ordering M.D.:

Copies To:

Age/Sex:
Location:

Assistant:
Date of Procedure:
Date Receiver

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. UTERUS, BILATERAL TUBE AND OVARIES, TOTAL ABDOMINAL HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY

Cervix

- Negative for malignancy
- Acute and chronic cervicitis

Endometrium

- Adenocarcinoma, endometrioid type, FIGO grade I of III (See comment)
- Background atrophic endometrium

Myometrium and serosa

- Endometrioid adenocarcinoma with focal superficial myoinvasion (less than 1/3 of inner myometrium) (See comment)
- No angiolymphatic invasion identified
- Serosa negative for malignancy and other pathologic findings

Right and left ovaries

- Negative for malignancy
- Endosalpingiosis, left ovary

Right and left fallopian tubes

- Negative for malignancy
- Features consistent with prior tubal ligation

AJCC Pathologic stage (2002, 6th Ed): pT1b/pNx

COMMENT: The myoinvasion is best seen in the permanent sections cut from the remaining tissue used for frozen section. It is superficial myometrial involvement mostly confined to the fibromuscular cores of the endometrioid papillary projections.

B. LEFT PELVIC LYMPH NODE, DISSECTION

- One lymph node negative for malignancy (1)

C. LEFT PERIAORTIC LYMPH NODE, DISSECTION

- One lymph node negative for malignancy (1)

D. RIGHT PELVIC LYMPH NODE, DISSECTION

- Fibrovascular and mature adipose tissue negative for malignancy; no lymph nodes identified

E. RIGHT PERIAORTIC LYMPH NODE, DISSECTION

Patient Case(s)

[page 2 of 3]
PATH #: [REDACTED]

- **Fibrovascular and mature adipose tissue negative for malignancy; no lymph nodes identified**

HISTORY: Endometrial cancer

MICROSCOPIC:
See diagnosis.

GROSS:

A. UTERUS, BILATERAL TUBE AND OVARIES

Labeled with the patient's name, labeled "uterus, bilateral tube and ovaries", and received in formalin is a 75 gram opened uterus with attached bilateral fallopian tubes and ovaries. The uterus measures 7.5 x 5.0 x 4.0 cm. The exocervix measures 3.0 x 2.5 cm. The endocervix measures 2.5 x 1.0 cm. The left ovary measures 1.7 x 1.0 x 0.5 cm. The right ovary measures 2.0 x 1.0 x 0.5 cm. The fallopian tubes are status post tubal ligation. The residual left fallopian tube measures 4.8 cm in length and 0.5 cm in width. The residual right fallopian tube measures 5.2 cm in length and 0.5 cm in diameter. The endometrial wall thickness is 0.6 cm. The myometrial wall thickness is 1.4 cm.

The endometrial surface is tan. On the posterior wall there is a cut firm tan mass which measures 2.0 x 1.8 x 0.6 cm. The serosal surface is shiny tan. There are no other lesions identified. The ectocervix and endocervix are grossly unremarkable. Representative sections.

- A1. Frozen section remnant - 6
- A2. Anterior cervix - 1
- A3. Posterior cervix - 1
- A4. Anterior lower uterine segment - 1
- A5. Posterior lower uterine segment - 1
- A6. Anterior endometrium - 1
- A7. Posterior endometrium - 1
- A8. Posterior mass to overlying serosal surface - 1
- A9. Posterior mass to overlying serosal surface - 1
- A10. Right ovary and fallopian tube - 4
- A11. Left ovary and fallopian tube - 4

B. LEFT PELVIC LYMPH NODE

Labeled with the patient's name, labeled "left pelvic lymph node", and received in formalin are six pieces of fibrofatty tissue ranging in size from 0.6 to 1.2 and aggregating to 2.5 x 2.0 x 0.7 cm. Entirely submitted.

- B1. 6

C. LEFT PERIAORTIC LYMPH NODE

Labeled with the patient's name, labeled "left periaortic lymph node", and received in formalin are three portions of fibrofatty tissue measuring from 0.5 to 1.5 cm in largest dimension and aggregating to 1.5 x 1.2 x 0.3 cm. Entirely submitted.

- C1. 3

D. RIGHT PELVIC LYMPH NODE

Labeled with the patient's name, labeled "right pelvic lymph node", and received in formalin is a piece of fibrofatty tissue measuring 2.3 x 0.8 x 0.5 cm. Entirely submitted.

- D1. 1

E. RIGHT PERIAORTIC LYMPH NODE

Labeled with the patient's name, labeled "right periaortic lymph node", and received in formalin are two pieces of fibrofatty tissue measuring 1.2 x 0.3 x 0.3 cm and 0.7 x 0.5 x 0.4 cm. Entirely submitted.

- E1. 2

[page 3 of 3]
PATH #: [REDACTED]

Gross dictated by

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

A. Uterus

- Endometrial adenocarcinoma
- "Only focal posterior superficial myometrial invasion seen" (I.D.)

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by

Those immunohistochemical tests have not been cleared or approved by the

U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

MD Electronically signed

Source: NCI Genomic Data Commons file 64982bf5-697d-433d-a024-c38bc50f581c (TCGA-A5-A0GP.A730192C-227E-4A86-96B9-8670D3F5EF59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).